Surgical pathology report (de-identified scan), TCGA case TCGA-RT-A6YC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Cleveland Clinic Foundation, specimen TCGA-RT-A6YC-01A (Primary Tumor).

[page 1 of 2]
Results

Patient Info

Patient Name Sex DOB

Results

Submitting Physician:

FINAL DIAGNOSIS

1. Right adrenal gland, adrenalectomy - Fragments of pheochromocytoma. (See comment)

COMMENT

Tumor shows areas of hemorrhage. Focal tumor cell spindling and marked nuclear pleomorphism are noted. Necrosis, capsular invasion, vascular invasion and extension into the peri-adrenal adipose tissue are not identified. Mitotic figures are <3/10 high power fields (HPF). The Pheochromocytoma of the Adrenal gland Scaled Score (PASS) for this tumor would be <4. Tumors with PASS <4 are expected to behave in a benign fashion. Tumors with PASS 4 have a potential for a biologically aggressive behavior.

(Electronic Signature)

SPECIMEN SUBMITTED

A: RIGHT ADRENAL GLAND

CLINICAL DATA

PHEOCHROMOCYTOMA

GROSS DESCRIPTION

A. Received fresh labeled "right adrenal gland" are multiple fragments of red-brown soft tissue aggregating to 12.0 x 9.0 x 3.1 cm and weighing 183.6 grams. The external surface of the tissue fragments is dusky brown. The tissue is firm and cut with little resistance. Minimal patchy areas of normal appearing adrenal gland are identified. No areas of necrosis or calcification are identified. Patchy areas of hemorrhage are present. Representative sections are submitted in formalin as follows: A1-A10 red-brown tissue; A11 possible normal adrenal.

[page 2 of 2]
Date of Report:
Date of Procedure:
Date of Receipt:
Submitted by:
Location:
Test performed by:

Lab and Collection

SURGICAL PATHOLOGY

- Lab and Collection Information

Result History

SURGICAL PATHOLOGY

Order Result History Report

Result Information

Result Date and Time

Status
Final result

Provider Status
Reviewed

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file 58a71d72-1560-43d8-9d90-b61b00151a42 (TCGA-RT-A6YC.CA2ABE95-B73A-4B22-AB9D-5F08B19571C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).